Gene-level copy-number profile of tumor specimen TCGA-D3-A51N-06A from TCGA case TCGA-D3-A51N, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.4 years (20,595 days).
Specimen TCGA-D3-A51N-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.37b45ef2-a6af-43ce-b95b-95177142d86a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A51N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/484db7aa-7707-4852-b31a-d998f51645ba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 124; copy number 1: 12,644; copy number 2: 42,352; copy number 3: 3,646; copy number 4: 1,001; copy number 5: 50; copy number 6: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A51N-06A-11D-A25P-01): tumor purity 0.53, ploidy 3.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 124 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:13,927,971–13,987,909, 2 genes: LINC00583, PES1P2.
- chr9:20,331,446–28,888,955, 122 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 51 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,252,006–1,523,962, 11 genes, copy number 5 (within-gene range 2–5): AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075.
- chr5:4,436,850–4,440,259, 1 gene, copy number 5: AC106799.3.
- chr5:4,512,262–4,516,776, 1 gene, copy number 5: AC106799.1.
- chr5:6,765,891–7,219,291, 8 genes, copy number 5 (within-gene range 2–5): LINC02236, AC122710.2, MIR4278, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1.
- chr5:7,707,802–7,749,766, 1 gene, copy number 5 (within-gene range 2–5): AC093305.1.
- chr5:13,144,000–13,190,677, 1 gene, copy number 5: AC016553.1.
- chr5:19,233,366–19,234,487, 1 gene, copy number 6: HSPD1P15.
- chr5:38,682,070–38,845,829, 4 genes, copy number 5 (within-gene range 2–5): AC010425.1, OSMR-AS1, AC091435.1, AC091435.2.
- chr5:59,314,110–59,314,800, 1 gene, copy number 5: AC008833.1.
- chr5:60,021,249–60,033,020, 1 gene, copy number 5: AC034234.1.
- chr5:62,403,972–62,628,582, 1 gene, copy number 5 (within-gene range 2–5): IPO11.
- chr5:62,512,246–62,777,263, 5 genes, copy number 5: CKS1BP3, AC114982.1, RPL35AP14, LRRC70, ISCA1P1.
- chr5:74,917,726–75,601,144, 13 genes, copy number 5 (within-gene range 2–5): AC116337.3, RPL27AP5, AC093259.1, GCNT4, ANKRD31, SUMO2P5, AC008897.2, HMGCR, CERT1, AC008897.3, AC008897.1, POLK, RNU7-175P.
- chr5:104,773,641–104,799,772, 2 genes, copy number 5: AC099520.2, RNU6-334P.

Autosomal genes at a single copy (total copy number 1): 12,625. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
